TCGA case TCGA-CZ-5469 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6205c2d8-d431-4c4c-8ac6-ee407170e833

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Dead; Days to death: 946 days (2.6 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 41.7 years (15,242 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 16.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 177 days; Days to treatment end: 191 days; Treatment dose: 3,750 cGy; Number of fractions: 15; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 203 days; Days to treatment end: 203 days; Treatment dose: 1,200 cGy; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Initial disease status: Progressive Disease; Days to treatment start: 223 days; Days to treatment end: 597 days (1.6 years); Prescribed dose: 37.5; Prescribed dose units: mg/day; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.0 years (15,352 days); Days to diagnosis: 110 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 110 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 946 days (2.6 years); Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Other.

Molecular and laboratory tests
- Hemoglobin: Low.
- Calcium: Low.
- Leukocytes: Elevated.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CZ-5469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.6; Shortest dimension: 0.3.
  Slide TCGA-CZ-5469-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CZ-5469-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CZ-5469-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CZ-5469-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 0.9; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 1.
- Drug treatment: Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: PO.
- Radiation treatment 1: Radiation type other: whole brain radiation; Therapy regimen: Progression.
- Radiation treatment 2: Radiation type other: SRS; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 946 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 946 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 110 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CZ-5469-01A-01D-1499-01): tumor purity 0.68, ploidy 4.99, whole-genome doublings 2.
